TCGA case TCGA-DU-6403 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8daa29c0-f652-4130-a004-5183bbe30c63

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 60 years; Vital status: Dead; Days to death: 354 days.

Diagnoses (1)
1. Mixed glioma: ICD-O-3 morphology code: 9382/3; ICD-10 code: C71.0; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Nervous system, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 60.3 years (22,031 days); Year of diagnosis: 1999; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; First symptom longest duration: 0-30 Days; First symptom prior to diagnosis: Headaches; Sites of involvement: Brain, Temporal lobe.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carmustine Implant; Treatment intent type: Adjuvant; Days to treatment start: 10 days; Days to treatment end: 10 days; Number of cycles: 1; Prescribed dose: 1; Prescribed dose units: Wafer; Route of administration: Intratumoral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Hydroxyurea; Treatment intent type: Adjuvant; Days to treatment start: 43 days; Days to treatment end: 74 days; Number of cycles: 1; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 43 days; Days to treatment end: 74 days; Course number: 1; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carmustine; Treatment intent type: Adjuvant; Days to treatment start: 104 days; Days to treatment end: 196 days; Number of cycles: 2; Route of administration: Intravenous.
   Treatment given: Treatment type: Steroid Therapy; Timepoint category: Preoperative.
   Recorded as not given: Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis.

Follow-up (2 entries)
- Day 207 (post adjuvant therapy): Karnofsky performance status: 90.
- Days to follow up: 354 days; Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Headache.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DU-6403-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.9; Intermediate dimension: 0.6; Shortest dimension: 0.5.
  Slide TCGA-DU-6403-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-DU-6403-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-DU-6403-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DU-6403-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Oligoastrocytoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy; Tumor site: Supratentorial, Temporal Lobe; Supratentorial localization: Not listed in Medical Record; History seizures: No; History headaches: Yes; Symp changes mental status: No; Symp changes visual: No; Symp changes sensory: No; Symp changes motor movement: No; First symptom longest duration: 0 - 30 Days; History neoadjuvant steroid treatment: Yes; Idh1 mutation test indicator: No.
- Drug treatment 1: Regimen number: 2; Pharmaceutical therapy drug name: BCNU (Carmustine).
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1.
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Drug treatment 3: Regimen number: 1; Pharmaceutical therapy drug name: Gliadel Wafer.
- Drug treatment 3, Route of administrations: Route of administration: Intum.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 354 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 354 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 354 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DU-6403-01A-11D-1704-01): tumor purity 0.71, ploidy 2, whole-genome doublings 0.
